Surgical pathology report (de-identified scan), TCGA case TCGA-NI-A4U2, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Roswell Park, specimen TCGA-NI-A4U2-01A (Primary Tumor).

[page 1 of 4]
SPECIMEN(S):

A. GALLBLADDER

B. LEFT LOBE OF LIVER

C. RT LOBE LIVER NODULE

D. NEW MARGIN OF SEG 6 LIVER

E. LEFT LOBE CLOSE PARANCHYMAL MARGIN

ICD-0-3

carcinoma, hepatocellular, nos 8170/3

Site: liver, nos C82-0

fw
10/10/12

CLINICAL HISTORY:

PRE-OPERATIVE DIAGNOSIS:

Left liver lobe tumor

INTRAOPERATIVE CONSULT:

B. Liver, left lobe, lobectomy: Approximately 0.2 cm from the closest parenchymal margin (marked by long suture).

GROSS DESCRIPTION:

GALLBLADDER

Received in formalin is a gallbladder measuring 7.5 x 2.5 x 1.0 cm. The serosal surface is smooth, glistening and grossly unremarkable. The posterior surface of the gallbladder is slightly granular and trabeculated but otherwise unremarkable. On opening the gallbladder it contains a moderate amount of pink black bile with no stones. The mucosa is velvety, green to yellow, the average wall thickness is 0.3 cm. No ulceration, mass or any other gross lesion is identified in the gallbladder. Representative sections are submitted in 1 cassette.

LEFT LOBE OF LIVER

Received fresh for tissue procurement and labeled "left lobe of liver" is a lobectomy of the liver weighing 1125 gm and measuring 20 x 18 x 9 cm. The serosal surface is smooth and tan with multiple bulging sub-serosal nodules. Dissections reveal multiple satellite tumor masses ranging from 1.0 x 1.5 x 0.5 cm to 13.0 x 12.8 x 8.5 cm. The largest mass shows confluence of the small fused mass with extension to the capsule but not through. Sections reveal gray, yellow and friable appearance, focally necrotic and hemorrhagic. There are two stitches attached to the parenchyma indicating the resection margin. One inked yellow and the other black. The major large tumor mass is 0.2 cm from the parenchymal margin, and the 2nd largest tumor mass to the inked black margin is 1.0 cm. The uninvolved parenchyma shows prominent dilated vessel and occult nodularity. Representative sections are submitted in 10 cassettes.

[page 2 of 4]
Cassette 1-3: the largest mass

Cassette 4-5: the 2nd largest mass

Cassette 6: the satellite mass

Cassette 7-8: random section including the yellow inked margin

Cassette 9: nodularity area of the uninvolved parenchyma

Cassette 10: prominent dilated vessel area

RIGHT LOBE LIVER NODULE

Received fresh and labeled "right lobe liver nodule segment 4" is a segment of liver measuring 3.5 x 2.8 x 3.0 cm. There are 3 stitches attached to specimen indicating superior-single short, medial-double short, lateral-double long. The specimen is inked as follows: superior-red, inferior-orange, lateral-yellow, medial-green and posterior-black. Serial sections reveal a well circumscribed tan gray soft tumor mass located underneath the capsule with less than 1 cm from it, measuring 1.5 x 1.2 x 1.0 cm. On sectioning, it reveals a granular appearance. The rest of the tissue is unremarkable. Representative sections are submitted in 6 cassettes.

Cassette 1-3: mass entirely submitted

Cassette 4-6: the random section

NEW MARGIN OF SEGMENT VI LIVER

Received fresh and labeled "new margin of segment VI lesion" is a irregular cauterized fragment of soft tissue measuring 6.0 x 3.0 x 1.5 cm. There are 3 stitches attached at one aspect of the specimen, which is inked in blue. Serial sections are unremarkable. Representative sections are submitted in 3 cassettes.

LEFT LOBE CLOSE PARENCHYMA MARGIN

Received in formalin are 2 irregular shaped brown to tan soft tissue measuring 2.4 x 1.8 x 0.5 cm and 3.6 x 0.9 x 0.2 cm. One of them is marked with a suture. Both portions are friable. The fragment marked with suture is falling apart after the suture is removed. These fragments are in cassette E1 after inked in black. The larger fragment is also inked in black and serial sectioned to reveal homogeneous tan to brown cut surface. Submitted in total in 3 cassettes.

DIAGNOSIS:

A. GALL BLADDER, CHOLECYSTECTOMY:

[page 3 of 4]
- NO HISTOPATHOLOGICAL ABNORMALITIES

B. LIVER, LEFT LOBE, LOBECTOMY:

- HEPATOCELLULAR CARCINOMA, WELL DIFFERENTIATED, SEE TEMPLATE.

- MULTIPLE NODULES

- LARGEST NODULE, 13.0 CM IN GREATEST DIMENSION

- 12.8 X 8.5 CM IN ADDITIONAL DIMENSIONS

- THE PARENCHYMAL MARGIN IS NEGATIVE FOR TUMOR

- THE TUMOR IS 0.2 CM FROM THE PARENCHYMAL MARGIN

- ANGIOLYMPHATIC INVASION IS PRESENT

- THE NON-NEOPLASTIC LIVER SHOWS FOCAL BRIDGING FIBROSIS AND BILE DUCT PROLIFERATION.

C. LIVER, RIGHT LOBE SEGMENT VI, PARTIAL SEGMENTECTOMY:

- HEPATOCELLULAR CARCINOMA, WELL DIFFERENTIATED.

- 1.5 CM IN GREATEST DIMENSION

- 1.2 X 1.0 CM ADDITIONAL DIMENSION

- INVOLVING THE MEDIAL AND INFERIOR MARGINS OF RESECTION (GREEN AND ORANGE INKS, SLIDE C1), SEE COMMENT.

- ANGIOLYMPHATIC INVASION IS PRESENT

- THE NON-NEOPLASTIC LIVER SHOWS FIBROUS EXPANSION OF PORTAL TRIADS.

D. LIVER RIGHT LOBE SEGMENT VI NEW MARGIN, EXCISION:

- NO MALIGNANCY IDENTIFIED, SEE COMMENT

E. LIVER, LEFT LOBE NEW PARENCHYMAL MARGIN, EXCISION:

- NO MALIGNANCY IDENTIFIED

COMMENT: The final parenchymal margin for the right lobe liver nodule (parts C and D) is negative for tumor (see part D).

[page 4 of 4]
LIVER NEOPLASM TEMPLATE

Specimen type:

Total left lobectomy and right segment VI

partial segmentectomy

Focality:

Multiple, right and left lobes

Tumor size:

13.0 cm greatest dimension

Additional dimensions: 12.8 x 8.5 cm

Histologic type:

Hepatocellular carcinoma

Histologic grade:

Well differentiated

Extent of invasion:

Confined to the liver

Margins (invasive tumor):

Parenchymal margin is uninvolved by

invasive carcinoma;

Angiolymphatic invasion:

Present

Additional pathologic findings:

Other: portal fibrosis

Lymph nodes:

N/A

Pathologic stage:

pT3 pNX pMX

	Yes	No
Discrepancy		
Discrepancy		
History		
Primary Noted		

10/10/12

Source: NCI Genomic Data Commons file ba90329d-afd7-4fff-83d0-92530be34484 (TCGA-NI-A4U2.3AC56788-7CF9-4E6E-B1B8-7620A33E32A0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).